Somatic mutation profile of tumor specimen TCGA-HZ-7289-01A (aliquot TCGA-HZ-7289-01A-11D-2154-08) from TCGA case TCGA-HZ-7289, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 77.1 years (28,174 days).
Specimen TCGA-HZ-7289-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 752353ef-c880-4543-a5cd-5fbf854a5057.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-7289-10A (Blood Derived Normal), aliquot TCGA-HZ-7289-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76318b6d-abc4-4c72-a037-ba187d3653c8

The open-access MAF lists 82 somatic variants for this specimen: 62 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 19, Nonsense Mutation 5, Frame Shift Del 2, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 245/523 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 129/367 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1560326065, COSV99293804; called by muse, mutect2, varscan2
- AFF3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100420156, COSV57869706; called by muse, mutect2, varscan2
- ANXA11 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1176166954, COSV99627534; called by muse, mutect2, varscan2
- ASPRV1 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 95/222 reads (43%) | catalogued as rs1400878909, COSV100208639; called by muse, mutect2, varscan2
- ATG10 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 86/371 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99967340; called by muse, mutect2, varscan2
- ATM | c.1899-2A>C p.X633_splice | Splice Site (SNP) | VAF 101/167 reads (60%) | catalogued as CS014124, COSV99592043; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2528G>C p.S843T | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as COSV100377180; called by muse, mutect2
- BCAT1 | c.599A>C p.N200T | Missense Mutation (SNP) | VAF 90/1838 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99679021; called by muse, mutect2
- BPTF | c.7403G>A p.R2468H | Missense Mutation (SNP) | VAF 68/319 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.374); catalogued as rs910602094, COSV100076081; called by muse, mutect2, varscan2
- CCR10 | c.1048T>G p.S350A | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.176); catalogued as COSV99227055; called by muse, mutect2, varscan2
- CD300LD | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 139/597 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564832234, COSV60083788; called by muse, mutect2, varscan2
- CLEC3A | c.130C>T p.R44C (on ENST00000651443; = p.R35C on NM_005752.6) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs750807541, COSV100222384; called by muse, mutect2, varscan2
- COQ6 | c.612G>T p.L204F | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99474200; called by muse, mutect2
- CXorf66 | c.334A>T p.M112L | Missense Mutation (SNP) | VAF 419/592 reads (71%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV100983950; called by muse, mutect2, varscan2
- DHX33 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1322028888, COSV99834522; called by muse, mutect2, varscan2
- DNAAF2 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); catalogued as COSV100024255, COSV100024276; called by muse, mutect2, varscan2
- DNMT3A | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as rs759818409, COSV53051621; called by muse, mutect2, varscan2
- DST | c.16666C>T p.Q5556* (on ENST00000361203 / NM_001374722.1; = p.Q3253* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99760193; called by muse, mutect2, varscan2
- EXD1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 85/141 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs144824409, COSV100153845; called by muse, mutect2, varscan2
- FAM184A | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 233/841 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100138393; called by muse, mutect2, varscan2
- FARS2 | c.1255C>A p.R419S | Missense Mutation (SNP) | VAF 107/223 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM153470, COSV99213268; called by muse, mutect2, varscan2
- FBXL16 | c.1231C>A p.Q411K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99556924; called by muse, mutect2
- FCN1 | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 63/400 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100878978; called by muse, mutect2, varscan2
- HBE1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 187/500 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1301082909, COSV53080244, COSV53080844; called by muse, mutect2, varscan2
- HCK | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99393826; called by muse, mutect2, varscan2
- KATNB1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.695); catalogued as rs782815927, COSV65548800; called by muse, mutect2, varscan2
- KBTBD12 | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV100675535; called by muse, mutect2, varscan2
- KRT6A | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 127/756 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs373927281; called by muse, mutect2, varscan2
- LRRK2 | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 115/632 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.61); catalogued as rs777298637, COSV54153167; called by muse, mutect2, varscan2
- MDM1 | c.1590T>G p.D530E | Missense Mutation (SNP) | VAF 457/671 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100292073; called by muse, mutect2, varscan2
- MFSD14B | c.703T>A p.S235T | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as COSV100942818; called by muse, mutect2, varscan2
- MGA | c.8867C>G p.A2956G (on ENST00000219905 / NM_001164273.1; = p.A2747G on NM_001080541.2) | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); catalogued as COSV54950660, COSV99581656; called by muse, mutect2
- MYO15A | c.3592C>T p.P1198S | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99234502; called by muse, mutect2, varscan2
- MYO3B | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759988252, COSV100511891; called by muse, mutect2, varscan2
- NELFCD | c.755C>T p.A252V (on ENST00000602795; = p.A234V on NM_198976.4) | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV100682990; called by muse, mutect2, varscan2
- NLRP13 | c.1004G>T p.W335L | Missense Mutation (SNP) | VAF 175/509 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100738548; called by muse, mutect2, varscan2
- OR8B8 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100045275; called by muse, mutect2, varscan2
- PLD3 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs756836297, COSV99397099; called by muse, mutect2, varscan2
- PLXNB1 | c.5306T>G p.V1769G | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99603462; called by muse, mutect2, varscan2
- PPP1R9A | c.2147C>A p.T716N | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs762406102, COSV99198871; called by muse, mutect2, varscan2
- PTPRH | c.1579G>T p.G527C | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV54750718, COSV99671478; called by muse, mutect2, varscan2
- RBM15 | c.1847G>T p.R616L | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs531496071, COSV100873515; called by muse, mutect2, varscan2
- RCC1L | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 146/630 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs1365468101; called by muse, mutect2, varscan2
- RGS22 | c.1946C>A p.T649N | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV100693838, COSV62660819; called by muse, mutect2, varscan2
- RTN1 | c.482T>A p.L161* | Nonsense Mutation (SNP) | VAF 39/486 reads (8%) | catalogued as COSV99956923; called by muse, mutect2
- SERPINB7 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 123/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs773699003, COSV100321048; called by muse, mutect2, varscan2
- SNX7 | c.1106A>G p.K369R | Missense Mutation (SNP) | VAF 118/649 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.065); catalogued as COSV100069481; called by muse, mutect2, varscan2
- SPAG17 | c.5033A>G p.E1678G | Missense Mutation (SNP) | VAF 160/465 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100310668; called by muse, mutect2, varscan2
- SVEP1 | c.9507G>C p.W3169C | Missense Mutation (SNP) | VAF 436/1285 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928676, COSV99929872; called by muse, mutect2, varscan2
- TBC1D17 | c.1445-1G>T p.X482_splice | Splice Site (SNP) | VAF 43/119 reads (36%) | catalogued as COSV99680954; called by muse, mutect2, varscan2
- TMEM108 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs780279321, COSV100419657; called by muse, mutect2, varscan2
- TMEM260 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 76/393 reads (19%) | catalogued as rs758076398; called by muse, mutect2, varscan2
- TOP2A | c.3346G>A p.D1116N | Missense Mutation (SNP) | VAF 112/224 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV101396403; called by muse, mutect2, varscan2
- TREX1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 166/1003 reads (17%) | catalogued as COSV99604196; called by muse, mutect2, varscan2
- TRMT13 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs1295485968, COSV100734580; called by muse, mutect2, varscan2
- UGT1A4 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 219/1210 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs762367100, COSV100531094, COSV59389879, COSV59396877; called by muse, mutect2, varscan2
- XIRP2 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 121/230 reads (53%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV99747755; called by muse, mutect2, varscan2
- ZBTB7A | c.1365C>G p.N455K | Missense Mutation (SNP) | VAF 93/318 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100475966; called by muse, mutect2, varscan2
- ZFYVE1 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV100607144; called by muse, mutect2, varscan2
- MYO10 | c.4579del p.Y1527Tfs*26 | Frame Shift Del (DEL) | VAF 127/394 reads (32%) | called by mutect2, pindel, varscan2
- RAD23B | c.203del p.N68Tfs*7 | Frame Shift Del (DEL) | VAF 84/505 reads (17%) | called by mutect2, pindel, varscan2
- ABHD1 | c.258C>T p.P86= | Silent (SNP) | VAF 185/441 reads (42%) | catalogued as COSV99574825; called by muse, mutect2, varscan2
- ADCY8 | c.3306C>T p.G1102= | Silent (SNP) | VAF 259/1086 reads (24%) | catalogued as rs145809062; called by muse, mutect2, varscan2
- ANKS1A | c.2790C>T p.H930= | Silent (SNP) | VAF 11/216 reads (5%) | catalogued as COSV100832862; called by muse, mutect2
- ARHGAP20 | c.471C>G p.G157= | Silent (SNP) | VAF 82/153 reads (54%) | catalogued as COSV99505426; called by muse, mutect2, varscan2
- CRYBB1 | c.294G>A p.A98= | Silent (SNP) | VAF 54/409 reads (13%) | catalogued as rs760235124, COSV53233444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB7 | c.483T>C p.G161= | Silent (SNP) | VAF 119/683 reads (17%) | catalogued as COSV99344452; called by muse, mutect2, varscan2
- FRYL | c.5163C>T p.S1721= | Silent (SNP) | VAF 76/202 reads (38%) | catalogued as rs1207223444, COSV99978253; called by muse, mutect2, varscan2
- ITPR2 | c.6888C>T p.L2296= | Silent (SNP) | VAF 46/427 reads (11%) | catalogued as COSV101190184; called by muse, mutect2, varscan2
- NCOR2 | c.5301C>T p.P1767= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1024773806, COSV100657909; called by muse, mutect2, varscan2
- OTOP3 | c.1308G>A p.S436= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as rs564764463, COSV100173081, COSV60914860; called by muse, mutect2, varscan2
- PGAP3 | c.228C>T p.T76= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs200486300, COSV100328730, COSV100328733; called by muse, mutect2, varscan2
- PPP1R3C | c.822C>T p.D274= | Silent (SNP) | VAF 78/347 reads (22%) | catalogued as COSV99491132; called by muse, mutect2, varscan2
- RANBP2 | c.3693C>T p.R1231= | Silent (SNP) | VAF 72/368 reads (20%) | catalogued as COSV99313383; called by muse, mutect2, varscan2
- TUBGCP6 | c.4719C>T p.D1573= | Silent (SNP) | VAF 87/277 reads (31%) | catalogued as rs754165072, COSV99956407; called by muse, mutect2, varscan2
- UGT1A6 | c.1491C>T p.V497= | Silent (SNP) | VAF 210/468 reads (45%) | catalogued as rs1254411333, COSV100531096; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP10 | c.1809C>T p.T603= | Silent (SNP) | VAF 203/488 reads (42%) | catalogued as rs370164533; called by muse, mutect2, varscan2
- ZNF302 | c.1302C>T p.H434= (on ENST00000627982; = p.H355= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/238 reads (17%) | catalogued as rs1423077739, COSV101416527; called by muse, mutect2, varscan2
- ZNF611 | c.1065A>G p.Q355= | Silent (SNP) | VAF 198/543 reads (36%) | catalogued as rs757510179, COSV100160631; called by muse, mutect2, varscan2
- ZNF707 | c.426C>T p.D142= | Silent (SNP) | VAF 43/195 reads (22%) | catalogued as rs889735581, COSV100690741; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7051G>T | Intron (SNP) | VAF 62/758 reads (8%) | catalogued as COSV63392119; called by muse, mutect2
